CCDI case PBCEEC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/7fcd262b-647e-40d6-8706-e00c4327e597

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 10.0 years (3,663 days).

Biospecimens (3 samples)
- Sample 0DQ2MZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ2NB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQ2OW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
